CCDI case PBBVTK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/ff8fb4e6-877e-4bf3-b62c-54fd1a959734

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyoma, NOS: ICD-O-3 morphology code: 8900/0; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 4.8 years (1,762 days).

Biospecimens (3 samples)
- Sample 0DIKJI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIKJQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIKK5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
